Gene-level copy-number profile of tumor specimen ALCH-ADC7-TTP1-A from ALCHEMIST case ALCH-ADC7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 59.7 years (21,790 days).
Specimen ALCH-ADC7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 38321c8b-8231-4a02-b32d-906fc58f229c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADC7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/abf36e61-00b5-4b4a-ab65-bcaa5acc430e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 2,426; copy number 2: 54,210; copy number 3: 1,517; copy number 4: 185; copy number 5: 6; copy number 6: 15; copy number 7: 2; copy number 8: 1; copy number 10: 7; copy number 15: 4; copy number 18: 2; copy number 19: 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:73,368,555–73,395,133, 4 genes (within-gene range 0–2): OOEP, OOEP-AS1, RPL39P3, RPS6P8.
- chr7:140,435,316–140,435,787, 1 gene: AC069335.1.
- chr11:70,646,165–70,647,562, 1 gene (within-gene range 0–1): SHANK2-AS2.
- chr15:20,344,736–20,359,166, 1 gene: AC026495.1.
- chr15:20,593,494–20,599,195, 1 gene: SPATA31E2P.
- chr16:88,731,180–88,741,425, 1 gene (within-gene range 0–3): AC138028.2.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 39 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,549,940–32,560,022, 2 genes, copy number 6 (within-gene range 4–6): RNU1-61P, HLA-DRB6.
- chr9:136,754,386–136,766,255, 2 genes, copy number 6–10: LCN8, LCN15.
- chr9:136,796,338–136,810,042, 2 genes, copy number 10 (within-gene range 3–10): CCDC183, AL355987.4.
- chr9:136,803,927–136,808,848, 1 gene, copy number 10 (within-gene range 3–10): CCDC183-AS1.
- chr10:132,965,534–132,976,354, 1 gene, copy number 6: LINC01168.
- chr14:105,093,609–105,100,131, 2 genes, copy number 6: LINC02298, AL512356.4.
- chr14:105,140,982–105,181,323, 4 genes, copy number 15 (within-gene range 15–35): JAG2, MIR6765, AL512356.1, NUDT14.
- chr14:105,472,962–105,488,947, 2 genes, copy number 6–7 (within-gene range 4–7): CRIP2, CRIP1.
- chr14:105,583,731–105,601,728, 2 genes, copy number 6–10 (within-gene range 2–10): IGHA2, IGHE.
- chr16:1,148,224–1,225,257, 7 genes, copy number 5–18: AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10.
- chr16:88,382,959–88,537,031, 4 genes, copy number 6–8: ZNF469, ZFPM1, MIR5189, AC116552.1.
- chr17:81,165,507–81,241,310, 6 genes, copy number 5–19 (within-gene range 2–19): PVALEF, CEP131, AC027601.2, TEPSIN, AC027601.1, NDUFAF8.
- chr19:1,852,382–1,863,579, 3 genes, copy number 6 (within-gene range 6–35): AC012615.3, KLF16, AC012615.4.
- chr22:20,148,416–20,151,055, 1 gene, copy number 6: CCDC188.

Autosomal genes at a single copy (total copy number 1): 2,395. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
